Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3MX, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3MX-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Department of Pathology,
Tel: -

DOB:
Physician:

Sex: F

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

- (A) LYMPH NODE, LEFT PARATRACHEAL, BIOPSY:
One benign lymph node (0/1).
- (B) PARATHYROID TISSUE, BIOPSY:
Parathyroid tissue identified.
- (C) THYROID, TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA (5.0 CM IN GREATEST DIMENSION).
TUMOR CONFINED TO THYROID.
One parathyroid lymph node, negative for tumor (0/1).

Entire report and diagnosis completed by

1CD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
1/7/12
w

GROSS DESCRIPTION

- (A) LEFT PARATRACHEAL LYMPH NODE - A 0.6 cm in diameter lymph node bisected and entirely submitted for frozen section diagnosis in A.
*FS/DX: BENIGN LYMPH NODE.
- (B) PARATHYROID TISSUE - A tiny soft tan-pink tissue measuring < 0.1 x 0.1 x 0.1 cm. Entirely submitted for frozen diagnosis in B.
*FS/DX: PARATHYROID PRESENT.
- (C) TOTAL THYROIDECTOMY - A total thyroidectomy (6.0 x 5.5 x 4.0 cm). The right thyroid lobe is unremarkable. The left thyroid lobe is entirely replaced by a fleshy tan tumor. Within the central portion of the tumor there is an area that is more solid and also contains calcifications. The tumor is surrounded by a thin capsule. The tumor measures 5.0 x 4.1 x 4.0 cm.
A portion of abnormal thyroid and tumor submitted to the tissue bank.
SECTION CODE: C1-C3, representative sections of the right thyroid; C4, isthmus; C5-C20, representative sections of the left thyroid tumor to include capsule.

CLINICAL HISTORY

History of thyroid cancer.

SNOMED CODES

T-B6000, M-80503

[page 2 of 2]
Surgical Pathology Report

Department of Pathology

Te

DOB:

Physician:

Sex: F

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

"Some tests reported here may have been developed and performance characteristics determined by
by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 1946882a-fa75-4b18-b1ec-7236df5b0a30 (TCGA-EL-A3MX.6D029C4F-445D-4ECC-8395-FAC6A422246E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).